MMRF case MMRF_1332 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a993cdf7-3efd-476d-8168-d6fc4cd883c2

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 32 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 33.0 years (12,044 days); ISS stage: I; Days to last known disease status: 515 days (1.4 years); Days to last follow up: 515 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 167 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 10 days; Days to treatment end: 167 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 201 days; Days to treatment end: 201 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 310 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 515.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 345 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.66 g/L; Beta 2 Microglobulin 2.74 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 12.7 ×10⁹/L; Absolute Neutrophil 9.2 ×10⁹/L; Platelets 343 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.65 mmol/L; Albumin 51 g/L; Total Protein 8.3 g/dL; Glucose 6.55 mmol/L; C-Reactive Protein 0.9 mg/dL.
- Day 74 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.63 mg/dL; Immunoglobulin G 5.38 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.37 g/L; Lactate Dehydrogenase 5.13 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 8.3 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.56 mmol/L.
- Day 171 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 6.32 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 5.67 mmol/L.
- Day 310 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 9.47 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.85 g/L; Lactate Dehydrogenase 7 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 7.6 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 5.61 mmol/L.
- Day 373 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.94 g/L; Lactate Dehydrogenase 6.47 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 4.9 mmol/L.
- Day 459 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 9.47 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.5 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day 1: Weight: 81 kg; Height: 172 cm.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples)
- Sample MMRF_1332_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1332_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1332_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 373 days (1.0 years).
